Gene-level copy-number profile of tumor specimen TCGA-GF-A769-01A from TCGA case TCGA-GF-A769, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 39.2 years (14,304 days).
Specimen TCGA-GF-A769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7c0cb55d-6bf2-445d-bd44-4bb7dc7f9665.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GF-A769-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a48eb138-8f64-482e-87c5-941e26924d47

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 4,844; copy number 2: 35,453; copy number 3: 17,824; copy number 4: 1,596; copy number 5: 73; copy number 6: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GF-A769-01A-32D-A32M-01): tumor purity 0.86, ploidy 2.3, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.
- chr12:54,802,746–54,896,008, 2 genes (within-gene range 0–1): VDAC1P5, MUCL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 84 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:7,951,263–8,611,924, 4 genes, copy number 5 (within-gene range 2–5): LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P.
- chr3:69,168,782–70,518,064, 11 genes, copy number 6 (within-gene range 3–6): FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2.
- chr8:37,784,191–38,468,834, 34 genes, copy number 5 (within-gene range 1–5): ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr17:1,344,275–1,900,082, 24 genes, copy number 5 (within-gene range 3–5): YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1.
- chr17:52,390,515–54,365,634, 11 genes, copy number 5 (within-gene range 4–5): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B.

Autosomal genes at a single copy (total copy number 1): 2,458. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
